TCGA case TCGA-CR-7389 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Larynx; Tissue source site: Vanderbilt University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5422a86d-f9ff-4fb6-873e-bf7cc3de50e5

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 55 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C32.9; Tissue or organ of origin: Larynx, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 55.2 years (20,169 days); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC clinical T: T2; AJCC clinical N: N1; AJCC clinical M: M0; AJCC clinical stage: Stage III; AJCC pathologic T: TX; AJCC pathologic N: NX; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 392 days (1.1 years).
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 31 days; Days to treatment end: 73 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Initial Diagnosis; Days to treatment start: 31 days; Days to treatment end: 75 days; Treatment dose: 6,930 cGy; Course number: 1; Number of fractions: 33; Treatment anatomic sites: Regional Site.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Initial Diagnosis; Days to treatment start: 31 days; Days to treatment end: 75 days; Treatment dose: 6,930 cGy; Course number: 1; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Radiation, External Beam; Initial disease status: Initial Diagnosis; Days to treatment start: 31 days; Days to treatment end: 75 days; Treatment dose: 5,610 cGy; Course number: 1; Number of fractions: 33; Treatment anatomic sites: Regional Site.

Follow-up (1 entry)
- Days to follow up: 392 days (1.1 years); Disease response: Tumor Free.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 34; Tobacco smoking onset year: 1974.
- Alcohol history: Yes; Alcohol drinks per day: 1; Alcohol days per week: 1.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CR-7389-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 0.1; Intermediate dimension: 0; Shortest dimension: 0.
  Slide TCGA-CR-7389-01A-01-TS1: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 75; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-CR-7389-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Lymph nodes examined: No; Lymph node neck dissection indicator: No; Tobacco smoking history indicator: 2; Alcohol consumption frequency: 1.
- Radiation treatment 1: Therapy regimen: OTHER, SPECIFY IN NOTES.
- Follow-up form: New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 392 days; disease-specific survival: no event (censored), 392 days; disease-free interval: no event (censored), 392 days; progression-free interval: no event (censored), 392 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CR-7389-01A-11D-2010-01): tumor purity 0.41, ploidy 2.58, whole-genome doublings 1.
